Gene-level copy-number profile of tumor specimen HTMCP-03-06-02205-01A from CGCI case HTMCP-03-06-02205, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Warty carcinoma; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 41.1 years (15,000 days).
Specimen HTMCP-03-06-02205-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9cdd4219-ebce-4cf6-ab2d-7400e3911d31.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02205-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/fc386756-e461-43d3-b64e-77684a98c800

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 435; copy number 3: 3,931; copy number 4: 28,365; copy number 5: 12,495; copy number 6: 7,782; copy number 7: 3,853; copy number 8: 1,513; copy number 9: 9; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:107,902,997–107,904,241, 2 genes, copy number 11: AC009963.2, AC009963.1.
- chr2:132,080,290–132,257,969, 7 genes, copy number 9: AC098826.3, AC098826.1, AC098826.2, ANKRD30BL, RNU6-1132P, RNA5-8SP5, MIR663B.
- chr8:43,672,823–43,674,591, 2 genes, copy number 9: AC139365.2, AC139365.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
